Somatic mutation profile of tumor specimen BA2421D (aliquot aq-BA2421D) from BEATAML1.0 case 2195, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.2 years (27,464 days).
Specimen BA2421D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d753e6de-9dd5-4815-aaba-5c5682c1687a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2140D (Solid Tissue Normal), aliquot aq-BA2140D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48eff7d0-be0a-4533-8547-c28cc7e63b6b

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Nonsense Mutation 4, Intron 3, RNA 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>C p.R882P | Missense Mutation (SNP) | VAF 17/54 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GIPC3 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs387907002, CM119959; ClinVar: pathogenic; called by muse, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 40/149 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CLDN17 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as COSV54523975; called by muse, mutect2, varscan2
- CLDN6 | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528018513; called by muse, mutect2, varscan2
- DNM3 | c.2581C>A p.R861S (on ENST00000355305 / NM_001350206.2; = p.R855S on NM_015569.5) | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.931); catalogued as COSV104414559; called by muse, mutect2, varscan2
- FMOD | c.775G>C p.V259L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV61610508; called by muse, mutect2, varscan2
- GAS8 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781205439, COSV99244254; called by muse, mutect2, varscan2
- IL12RB1 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs376248199, CD109704; called by muse, mutect2, varscan2
- ITIH5 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs768826767, COSV53662968; called by muse, mutect2, varscan2
- KIFC3 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1555607863, COSV65550924; called by muse, mutect2
- NAB1 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61609554; called by muse, mutect2, varscan2
- PDS5B | c.1180A>T p.R394* | Nonsense Mutation (SNP) | VAF 35/117 reads (30%) | catalogued as rs750827034, COSV59724936; called by muse, mutect2, varscan2
- RIMS1 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs895247293, COSV99323507; called by muse, mutect2, varscan2
- TSC2 | c.4044C>G p.H1348Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.03); catalogued as COSV51927584; called by muse, mutect2, varscan2
- XKR4 | c.1800C>G p.F600L | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV100531233; called by muse, mutect2, varscan2
- ADAM12 | c.1451A>T p.D484V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2
- AGR3 | c.98C>G p.T33R | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CASKIN1 | c.3127G>C p.V1043L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); called by muse, varscan2
- CYLD | c.735A>T p.E245D | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYP4A11 | c.1088G>A p.W363* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- KCND2 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OIP5 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OTOG | c.2531G>A p.C844Y | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PHF6 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 76/100 reads (76%) | called by muse, varscan2
- PRR12 | c.743C>G p.P248R (on ENST00000615927; = p.P1069R on NM_020719.3) | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGL3 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- RUSC1 | c.1004C>A p.A335E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); called by muse, mutect2
- SEPTIN7 | c.988C>A p.Q330K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2
- TENM2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2
- TMEM232 | c.1740del p.Y581Ifs*24 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | called by mutect2, pindel, varscan2
- ZNF280A | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNA1B | c.1158C>T p.N386= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs540276648; called by muse, varscan2
- CDHR2 | c.3183C>T p.G1061= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs1246629739; called by muse, mutect2, varscan2
- FBXW11 | c.363C>T p.T121= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs748688441; called by muse, mutect2, varscan2
- GDF5 | c.771C>T p.G257= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs76603468, COSV65503186; called by muse, mutect2
- KATNIP | c.2529G>A p.Q843= | Silent (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1569G>C p.S523= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- MICALL2 | c.699G>A p.P233= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs771559442; called by muse, mutect2, varscan2
- MYH8 | c.4494C>G p.L1498= | Silent (SNP) | VAF 132/419 reads (32%) | catalogued as COSV67969173; called by muse, mutect2, varscan2
- NRXN2 | c.4401C>T p.A1467= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs761002145, COSV55464714; called by muse, mutect2, varscan2
- OR5D14 | c.579T>C p.D193= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as rs768181412, COSV59458340; called by muse, mutect2, varscan2
- OSBPL5 | c.1821G>T p.V607= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- REG1A | c.282T>C p.D94= | Silent (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- RSBN1 | c.2046C>T p.V682= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as rs1434722155; called by muse, mutect2, varscan2
- XPO7 | c.1404G>A p.S468= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as rs1318427133; called by muse, mutect2, varscan2
- ABHD5 | c.-22C>G | 5'UTR (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99185461; called by muse, varscan2
- COL6A4P1 | n.757G>C | RNA (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- DNASE2 | c.512-9G>C | Intron (SNP) | VAF 76/237 reads (32%) | called by muse, mutect2, varscan2
- FAAP100 | c.1404-213A>C | Intron (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- NFASC | c.3019+169C>G | Intron (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
